Somatic mutation profile of tumor specimen TCGA-B5-A0JY-01A (aliquot TCGA-B5-A0JY-01A-11D-A10B-09) from TCGA case TCGA-B5-A0JY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 50.6 years (18,475 days).
Specimen TCGA-B5-A0JY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68120cbe-436b-4c3e-a317-39414cb7cdcb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0JY-10A (Blood Derived Normal), aliquot TCGA-B5-A0JY-10A-01D-A10O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cab2ba7-16bc-47a4-85c9-0e408d1365a0

The open-access MAF lists 11,089 somatic variants for this specimen: 8,815 protein-altering or splice-affecting, 2,047 silent, 227 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7,400, Silent 2,047, Nonsense Mutation 1,144, Splice Site 148, Intron 90, RNA 71, Splice Region 61, Frame Shift Ins 40, 3'UTR 26, 3'Flank 16, 5'UTR 13, 5'Flank 11.

Variants (750 of 11,089; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 33/115 reads (29%) | catalogued as rs72650697, CM073953, COSV52741670, COSV99227993; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGA | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 97/309 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs386833423, CM1212279, COSV52805913; ClinVar: likely pathogenic; called by muse, varscan2
- ALMS1 | c.8005C>T p.R2669* | Nonsense Mutation (SNP) | VAF 28/102 reads (27%) | catalogued as rs549857076, CM050170, COSV52503066; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.6610C>T p.R2204* | Nonsense Mutation (SNP) | VAF 25/62 reads (40%) | catalogued as rs752654519, COSV57326468, COSV99965912; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.6709C>T p.R2237* | Nonsense Mutation (SNP) | VAF 29/109 reads (27%) | catalogued as rs768922431, CM130062, COSV57327470; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5138T>C p.L1713P | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs797045264, COSV61374077, COSV61380164; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 69/250 reads (28%) | hotspot (GDC flag); catalogued as rs772821016, CM030188, CS991299, COSV53725394; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP1A2 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs28933401, CM032182, COSV63402942; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- CACNA1F | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 44/132 reads (33%) | catalogued as rs797044676, CM010174, COSV59903636; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEP290 | c.4966G>T p.E1656* | Nonsense Mutation (SNP) | VAF 91/240 reads (38%) | catalogued as rs62638179, CM063894, COSV58350032; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL17A1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 78/246 reads (32%) | catalogued as rs121912774, CM001969, COSV62225489; ClinVar: pathogenic; called by muse, varscan2
- CPS1 | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 39/141 reads (28%) | catalogued as rs759201450, COSV51805317, COSV99028158; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CPT1A | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80356775, CM014336, COSV55757639; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CTNNA2 | c.2788C>T p.R930* (on ENST00000402739 / NM_001282597.3; = p.R882* on NM_004389.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/50 reads (42%) | catalogued as rs760139097, COSV58133839, COSV58164977; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 21/69 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTSK | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 153/410 reads (37%) | catalogued as rs375958814, CM144771, CM990449, COSV55011043; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DSP | c.3316G>T p.E1106* | Nonsense Mutation (SNP) | VAF 50/161 reads (31%) | catalogued as rs1131691673, COSV65791931; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EEF1A2 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.972); catalogued as rs886041197, COSV53205280; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EP300 | c.4933C>T p.R1645* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | catalogued as rs139310551, CM153495, COSV54327123, COSV54342894; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EXT2 | c.544C>T p.R182* (on ENST00000343631; = p.R215* on NM_000401.3) | Nonsense Mutation (SNP) | VAF 46/147 reads (31%) | catalogued as rs886039358, CM000143, COSV59148031; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EYA4 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 97/324 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.801); catalogued as COSV62046082, COSV62054147; called by muse, mutect2, varscan2
- F8 | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852435, CM920257, COSV64271004; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FAM126A | c.414+1G>T p.X138_splice | Splice Site (SNP) | VAF 67/219 reads (31%) | catalogued as rs72549406, CS064403, COSV101300019; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FIG4 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 128/376 reads (34%) | catalogued as rs753207473, COSV57785952; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- FOXG1 | c.700T>C p.S234P | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786205008, CM113877, COSV57395902, COSV57397963; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FUBP1 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 75/286 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408536007, COSV53927182; called by muse, mutect2, varscan2
- GABRA1 | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs796052492, COSV50099369, COSV50100120; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- GAN | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 42/137 reads (31%) | catalogued as rs119485090, CM020938, COSV101633963; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KDM5C | c.2296C>T p.R766W | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199422238, CM080420, COSV64763624; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 36/130 reads (28%) | catalogued as rs1303773212, COSV70342690; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- LAMA2 | c.7732C>T p.R2578* | Nonsense Mutation (SNP) | VAF 58/174 reads (33%) | catalogued as rs121913572, CM032280, COSV70342710, COSV70355586; ClinVar: pathogenic; called by muse, varscan2
- LHCGR | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 90/292 reads (31%) | catalogued as rs773279269, COSV54294553, COSV54296553; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 45/127 reads (35%) | hotspot (GDC flag); catalogued as rs63751411, CM981314, COSV51876952; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.1921G>T p.E641* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as rs1553413305, COSV52276353; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTOR | c.7500T>G p.I2500M | Missense Mutation (SNP) | VAF 137/366 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1057519915, COSV63869436; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.4300C>T p.R1434C | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs730880800, CM115853, COSV62517542; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MYO18B | c.6322C>T p.R2108* | Nonsense Mutation (SNP) | VAF 24/125 reads (19%) | catalogued as rs773193391, CM161263, COSV59129183; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 139/407 reads (34%) | hotspot (GDC flag); catalogued as rs778405030, CM950845, COSV62197118; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 110/311 reads (35%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.3440G>A p.R1147Q | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs587783921, COSV56940971; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 52/166 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PRPF31 | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as rs868538598, CM1310332, COSV58084812; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PSMD12 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 65/250 reads (26%) | catalogued as rs1114167442, COSV62065273; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 138/372 reads (37%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTPRD | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 133/344 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs764400127, COSV61926988, COSV61964410; called by muse, mutect2, varscan2
- RHO | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs104893769, CM910325, COSV56212828; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RICTOR | c.3302C>T p.S1101L | Missense Mutation (SNP) | VAF 61/179 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs776074870, COSV57119127; called by muse, mutect2, varscan2
- RPE65 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs61751282, CM012457, COSV52013003; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- RSPH4A | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 44/127 reads (35%) | catalogued as rs1034327724, COSV57633705; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SATB2 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057518190, COSV53480467, COSV99611466; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SBF2 | c.2578C>T p.R860* | Nonsense Mutation (SNP) | VAF 50/186 reads (27%) | catalogued as rs764814296, COSV56294653; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.3007C>A p.L1003I | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs121917754, CM040796, COSV51835958; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCAL1 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 32/85 reads (38%) | catalogued as rs119473034, CM020304, COSV100620049; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SUZ12 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 94/330 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs1443094716, COSV59498812; called by muse, mutect2, varscan2
- TBX19 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 95/295 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs748717639, COSV63197049; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TCF4 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 62/198 reads (31%) | catalogued as rs878853149, CM120282, COSV61890253; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP63 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121908840, CM992697, CP015822, COSV99288642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 57/171 reads (33%) | catalogued as rs900140738, COSV53196111; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC22D2 | c.2204C>A p.S735Y | Missense Mutation (SNP) | VAF 75/192 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62622374, COSV62622441; called by muse, mutect2, varscan2
- UNC13D | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as rs1274685768, CM081468, COSV52882834; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.13576C>T p.R4526* | Nonsense Mutation (SNP) | VAF 55/150 reads (37%) | catalogued as rs1003869920, CM115977, COSV56326318; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1437C>A p.F479L (on ENST00000373993 / NM_138932.2; = p.F471L on NM_014576.4) | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.123); catalogued as COSV50959314; called by muse, mutect2, varscan2
- A1CF | c.697C>A p.L233I | Missense Mutation (SNP) | VAF 85/232 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV50959369; called by muse, mutect2, varscan2
- A2M | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.189); catalogued as COSV59384295; called by muse, mutect2, varscan2
- A2ML1 | c.2678G>A p.R893Q | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs780281065, COSV55287724; called by muse, mutect2, varscan2
- A2ML1 | c.2765-1G>T p.X922_splice | Splice Site (SNP) | VAF 65/214 reads (30%) | catalogued as COSV55287731, COSV55296008; called by muse, mutect2, varscan2
- A2ML1 | c.3375G>T p.K1125N | Missense Mutation (SNP) | VAF 83/287 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); catalogued as rs774567479, COSV55287745, COSV55291088; called by muse, mutect2, varscan2
- A3GALT2 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.629); catalogued as COSV100378221; called by muse, mutect2, varscan2
- A4GALT | c.777G>T p.K259N | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV50744163; called by muse, mutect2, varscan2
- A4GNT | c.815A>G p.Y272C | Missense Mutation (SNP) | VAF 88/251 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777531048, COSV52628622; called by muse, mutect2, varscan2
- A4GNT | c.580A>T p.I194L | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV52628631; called by muse, mutect2, varscan2
- AACS | c.135G>T p.E45D | Missense Mutation (SNP) | VAF 20/506 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV99908263; called by muse, mutect2
- AADAC | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs267599657, COSV51758590, COSV99233113; called by muse, mutect2, varscan2
- AADACL4 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.873); catalogued as rs1257201912, COSV66105972; called by muse, mutect2, varscan2
- AADAT | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV61786973; called by muse, mutect2, varscan2
- AAGAB | c.265-1G>T p.X89_splice | Splice Site (SNP) | VAF 80/266 reads (30%) | catalogued as COSV56016346; called by muse, mutect2, varscan2
- AANAT | c.168C>A p.F56L | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51683997; called by muse, mutect2, varscan2
- AARS2 | c.2861C>T p.A954V | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs747312867, COSV55113970; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AASS | c.1456C>A p.L486I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as COSV62789414; called by muse, mutect2, varscan2
- AATK | c.452C>A p.A151D (on ENST00000326724 / NM_001080395.3; = p.A48D on NM_004920.2) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV58686101; called by muse, mutect2, varscan2
- ABCA1 | c.5702G>T p.R1901I | Missense Mutation (SNP) | VAF 102/318 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV66064710; called by muse, varscan2
- ABCA1 | c.2705A>G p.Q902R | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66064715; called by muse, mutect2, varscan2
- ABCA10 | c.4327G>A p.E1443K | Missense Mutation (SNP) | VAF 86/367 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.147); catalogued as COSV52219882, COSV52226347; called by muse, varscan2
- ABCA10 | c.3692A>C p.K1231T | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52219894; called by muse, mutect2, varscan2
- ABCA10 | c.2539G>T p.D847Y | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV52218077; called by muse, mutect2, varscan2
- ABCA10 | c.1007-2A>C p.X336_splice | Splice Site (SNP) | VAF 37/97 reads (38%) | catalogued as COSV52219913; called by muse, mutect2, varscan2
- ABCA12 | c.4915G>A p.D1639N (on ENST00000272895 / NM_173076.3; = p.D1321N on NM_015657.3) | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886055608, COSV55953057; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.320A>G p.K107R | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV70026869; called by muse, mutect2, varscan2
- ABCA13 | c.751G>T p.V251L | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.21); catalogued as COSV70026875; called by muse, mutect2, varscan2
- ABCA13 | c.1423G>T p.D475Y | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as COSV70026883; called by muse, varscan2
- ABCA13 | c.4305A>C p.L1435F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV101330160; called by muse, mutect2, varscan2
- ABCA13 | c.5769G>T p.K1923N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV70026891; called by muse, mutect2, varscan2
- ABCA13 | c.11124G>T p.Q3708H | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101447174; called by muse, mutect2
- ABCA13 | c.11547G>T p.K3849N | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71284865; called by muse, mutect2, varscan2
- ABCA13 | c.13598G>A p.R4533H | Missense Mutation (SNP) | VAF 63/257 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747899889, COSV68944659; called by muse, mutect2, varscan2
- ABCA13 | c.14479G>A p.G4827R | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560141424, COSV68944665, COSV68951015; called by muse, mutect2, varscan2
- ABCA13 | c.15092A>C p.N5031T | Missense Mutation (SNP) | VAF 74/241 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV68944680; called by muse, mutect2, varscan2
- ABCA3 | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.054); catalogued as rs376672600; called by muse, mutect2, varscan2
- ABCA4 | c.4825C>A p.L1609I | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.306); catalogued as COSV64672070; called by muse, mutect2, varscan2
- ABCA4 | c.1323C>A p.F441L | Missense Mutation (SNP) | VAF 101/373 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as COSV64672078; called by muse, mutect2, varscan2
- ABCA5 | c.4427G>A p.R1476Q | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs750426352, COSV67015792; called by muse, mutect2, varscan2
- ABCA5 | c.3484A>C p.I1162L | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67016135; called by muse, mutect2, varscan2
- ABCA5 | c.3386A>T p.K1129I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV101201268; called by muse, varscan2
- ABCA6 | c.4801G>A p.E1601K | Missense Mutation (SNP) | VAF 84/341 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV52636877; called by muse, mutect2, varscan2
- ABCA6 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs745713208, COSV52636883; called by muse, varscan2
- ABCA6 | c.2646G>T p.K882N | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV52636891; called by muse, varscan2
- ABCA7 | c.39G>T p.K13N | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54026436; called by muse, mutect2, varscan2
- ABCA7 | c.2308C>T p.R770W | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs557493808, COSV54026446; called by muse, mutect2, varscan2
- ABCA8 | c.3593C>A p.S1198Y | Missense Mutation (SNP) | VAF 111/364 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV52197160; called by muse, mutect2, varscan2
- ABCA8 | c.2159-1G>T p.X720_splice | Splice Site (SNP) | VAF 82/231 reads (35%) | catalogued as COSV52197173; called by muse, mutect2, varscan2
- ABCA8 | c.2150A>C p.K717T | Missense Mutation (SNP) | VAF 156/463 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV52197191, COSV52200689; called by muse, varscan2
- ABCA9 | c.3605T>C p.V1202A | Missense Mutation (SNP) | VAF 85/277 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs989303548, COSV60622324; called by muse, mutect2, varscan2
- ABCB10 | c.1963C>A p.L655I | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs766317703, COSV60620340; called by muse, mutect2, varscan2
- ABCB11 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200667815, COSV55587544; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB4 | c.3318A>C p.E1106D (on ENST00000265723 / NM_018849.3; = p.E1099D on NM_000443.4) | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV55933483; called by muse, mutect2, varscan2
- ABCB5 | c.1963A>G p.K655E (on ENST00000404938 / NM_001163941.2; = p.K210E on NM_178559.6) | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.341); catalogued as COSV51705933; called by muse, mutect2, varscan2
- ABCB5 | c.2605G>T p.E869* (on ENST00000404938 / NM_001163941.2; = p.E424* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 89/280 reads (32%) | catalogued as COSV51705948; called by muse, mutect2, varscan2
- ABCB7 | c.2056G>A p.E686K (on ENST00000373394 / NM_001271696.3; = p.E687K on NM_004299.6) | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201312449, COSV53718754; called by muse, mutect2, varscan2
- ABCC1 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 72/213 reads (34%) | catalogued as COSV60682531; called by muse, mutect2, varscan2
- ABCC1 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60679996; called by muse, varscan2
- ABCC11 | c.3980G>T p.C1327F | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62321985; called by muse, mutect2, varscan2
- ABCC11 | c.3096G>T p.Q1032H | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV62321992; called by muse, mutect2, varscan2
- ABCC11 | c.1412G>T p.S471I | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV62321997; called by muse, mutect2, varscan2
- ABCC11 | c.1036C>A p.L346I | Missense Mutation (SNP) | VAF 75/228 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV62322005; called by muse, mutect2, varscan2
- ABCC11 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.062); catalogued as rs199620156, COSV62322013; called by muse, varscan2
- ABCC12 | c.2727G>A p.M909I | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV60912605, COSV60918149; called by muse, mutect2, varscan2
- ABCC2 | c.2500C>A p.L834M | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as COSV64985184; called by muse, varscan2
- ABCC2 | c.2571G>T p.K857N | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV64985190; called by muse, varscan2
- ABCC3 | c.3322A>G p.T1108A | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV53318939; called by muse, mutect2, varscan2
- ABCC6 | c.2416A>G p.T806A | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV52742260; called by muse, mutect2, varscan2
- ABCC6 | c.1825G>T p.E609* | Nonsense Mutation (SNP) | VAF 37/93 reads (40%) | catalogued as rs749334729, COSV52742271, COSV52747255; called by muse, mutect2, varscan2
- ABCC6 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 29/92 reads (32%) | catalogued as COSV99229524; called by muse, mutect2, varscan2
- ABCC9 | c.4523C>A p.S1508Y | Missense Mutation (SNP) | VAF 95/284 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV53965693; called by muse, varscan2
- ABCC9 | c.2210C>T p.S737F | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV53965701; called by muse, varscan2
- ABCD3 | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 81/231 reads (35%) | catalogued as rs1557691806, COSV64642599; called by muse, mutect2, varscan2
- ABCG2 | c.882C>A p.F294L | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.335); catalogued as COSV52944467; called by muse, mutect2, varscan2
- ABCG2 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 111/375 reads (30%) | catalogued as COSV52944493, COSV52945379, COSV99419957; called by muse, mutect2, varscan2
- ABHD12 | c.1100A>G p.D367G | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.501); catalogued as COSV53816834; called by muse, mutect2, varscan2
- ABHD17B | c.688A>C p.I230L | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.393); catalogued as COSV61007308; called by muse, mutect2, varscan2
- ABHD17B | c.233G>T p.R78I | Missense Mutation (SNP) | VAF 110/321 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV61007321; called by muse, mutect2, varscan2
- ABI1 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV100697997, COSV61015898; called by muse, mutect2, varscan2
- ABI1 | c.1335G>T p.K445N | Missense Mutation (SNP) | VAF 97/293 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV61015312; called by muse, mutect2, varscan2
- ABI3 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs553060450, COSV56799024; called by muse, mutect2
- ABI3BP | c.2493G>T p.Q831H | Missense Mutation (SNP) | VAF 239/720 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV52531591, COSV99428934; called by muse, mutect2, varscan2
- ABI3BP | c.1912C>A p.P638T | Missense Mutation (SNP) | VAF 93/339 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV52531614; called by muse, mutect2, varscan2
- ABI3BP | c.1184A>G p.E395G | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as COSV52531637; called by muse, mutect2, varscan2
- ABL2 | c.3430G>A p.E1144K (on ENST00000502732 / NM_007314.4; = p.E1129K on NM_005158.5) | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV61012123; called by muse, mutect2, varscan2
- ABL2 | c.1923G>T p.E641D (on ENST00000502732 / NM_007314.4; = p.E626D on NM_005158.5) | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.005); catalogued as COSV61012136; called by muse, mutect2, varscan2
- ABL2 | c.262G>A p.A88T (on ENST00000502732 / NM_007314.4; = p.A73T on NM_005158.5) | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.366); catalogued as COSV100773102, COSV61012148; called by muse, mutect2, varscan2
- ABLIM3 | c.812T>G p.L271* | Nonsense Mutation (SNP) | VAF 103/245 reads (42%) | catalogued as COSV58640559; called by muse, varscan2
- ABLIM3 | c.1316A>G p.N439S | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV58640567; called by muse, mutect2, varscan2
- ABR | c.1713G>T p.E571D (on ENST00000302538 / NM_021962.5; = p.E534D on NM_001092.5) | Missense Mutation (SNP) | VAF 138/538 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV52143330; called by muse, mutect2, varscan2
- ABT1 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.058); catalogued as COSV51290812, COSV99223419; called by muse, mutect2, varscan2
- ABTB2 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as COSV54385708; called by muse, mutect2, varscan2
- AC004593.2 | c.398G>T p.R133I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1037161011, COSV56089429; called by muse, mutect2, varscan2
- AC004922.1 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs145131136; called by muse, mutect2, varscan2
- AC006059.2 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs182436192, COSV59606181; called by muse, mutect2, varscan2
- AC011455.2 | c.851T>A p.I284N | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55498995; called by muse, mutect2, varscan2
- AC011462.1 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 38/119 reads (32%) | catalogued as COSV54196324; called by muse, mutect2, varscan2
- AC023055.1 | c.1406G>T p.R469I | Missense Mutation (SNP) | VAF 59/277 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs775763541, COSV60242850; called by muse, mutect2, varscan2
- AC090517.4 | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs777989146, COSV50996138; called by muse, mutect2, varscan2
- AC097636.1 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371775341; called by muse, mutect2, varscan2
- AC105001.2 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 80/274 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as rs1423031572, COSV59108648; called by muse, varscan2
- AC126283.2 | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs889240004, COSV67098130; called by muse, mutect2, varscan2
- AC126283.2 | c.915A>C p.E305D | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.561); catalogued as COSV67098135; called by muse, mutect2, varscan2
- AC244197.3 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV61711648; called by muse, mutect2, varscan2
- AC245033.1 | c.381+1G>A p.X127_splice | Splice Site (SNP) | VAF 115/326 reads (35%) | catalogued as COSV55617827; called by muse, mutect2, varscan2
- ACACA | c.3128A>G p.Y1043C | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as rs756018152; called by muse, mutect2, varscan2
- ACACA | c.3038G>A p.R1013Q | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1223416494; called by muse, mutect2, varscan2
- ACAD10 | c.472A>C p.N158H | Missense Mutation (SNP) | VAF 104/301 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58155099; called by muse, mutect2, varscan2
- ACAD10 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 87/233 reads (37%) | catalogued as COSV58155108; called by muse, mutect2, varscan2
- ACAD11 | c.107T>C p.F36S | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV53894667; called by muse, mutect2, varscan2
- ACAD9 | c.722A>C p.K241T | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV58306874; called by muse, mutect2, varscan2
- ACADL | c.707A>G p.E236G | Missense Mutation (SNP) | VAF 128/373 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV52052651; called by muse, mutect2, varscan2
- ACAN | c.4301C>A p.S1434Y | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61357887; called by muse, mutect2, varscan2
- ACAN | c.4613C>A p.S1538Y | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61357898; called by muse, mutect2, varscan2
- ACAN | c.5137A>T p.T1713S | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.561); catalogued as COSV61357908; called by muse, mutect2, varscan2
- ACAN | c.5317C>T p.L1773F | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.964); catalogued as COSV61357916, COSV61369764; called by muse, varscan2*
- ACAP3 | c.873C>A p.F291L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100686736; called by muse, mutect2
- ACAT1 | c.80G>T p.R27I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV54920351; called by muse, mutect2, varscan2
- ACAT1 | c.574C>A p.H192N | Missense Mutation (SNP) | VAF 91/313 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54920355; called by muse, mutect2, varscan2
- ACBD3 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766741908, COSV64729849; called by muse, mutect2, varscan2
- ACE | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746397573, COSV52003879; ClinVar: uncertain significance; called by muse, varscan2
- ACE | c.2831C>T p.S944L | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52004764; called by muse, mutect2, varscan2
- ACER1 | c.203T>G p.I68S | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV56835005; called by muse, mutect2, varscan2
- ACHE | c.1145A>C p.E382A | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV53816219; called by muse, mutect2, varscan2
- ACIN1 | c.3499C>T p.R1167W | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as COSV52975035; called by muse, mutect2, varscan2
- ACOX1 | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV53131966; called by muse, mutect2, varscan2
- ACOX3 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 34/92 reads (37%) | catalogued as rs545024479, COSV62711330; called by muse, mutect2, varscan2
- ACP1 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 48/125 reads (38%) | catalogued as rs553260669, COSV55242736, COSV55243751; called by muse, mutect2, varscan2
- ACP7 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs758657182, COSV58698590; called by muse, mutect2, varscan2
- ACRBP | c.849G>T p.E283D | Missense Mutation (SNP) | VAF 98/304 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV57523372; called by muse, mutect2, varscan2
- ACRV1 | c.178T>G p.S60A | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV59754682; called by muse, mutect2, varscan2
- ACSL4 | c.914G>T p.R305I (on ENST00000340800 / NM_022977.2; = p.R264I on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as COSV61613766; called by muse, mutect2, varscan2
- ACSM2B | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 38/122 reads (31%) | catalogued as COSV61657257; called by muse, varscan2
- ACSM2B | c.996G>T p.Q332H | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV61657261; called by muse, varscan2
- ACTBL2 | c.845C>A p.S282Y | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV70661063, COSV70661100; called by muse, mutect2, varscan2
- ACTL6B | c.863A>G p.N288S | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV50514090; called by muse, mutect2, varscan2
- ACTL8 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs142436980; called by muse, mutect2, varscan2
- ACTN2 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 92/277 reads (33%) | catalogued as COSV63973390; called by muse, mutect2, varscan2
- ACTR1B | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV56703533; called by muse, mutect2, varscan2
- ACTRT1 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV64419074; called by muse, mutect2, varscan2
- ADA2 | c.1365C>A p.F455L (on ENST00000262607; = p.F214L on NM_177405.3) | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52830751, COSV52833578; called by muse, mutect2, varscan2
- ADAD1 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as rs546801281, COSV56642389; called by muse, mutect2, varscan2
- ADAD1 | c.1717C>T p.Q573* | Nonsense Mutation (SNP) | VAF 53/162 reads (33%) | catalogued as COSV56642398; called by muse, mutect2, varscan2
- ADAM15 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.79); catalogued as rs754878868, COSV99665288; called by muse, mutect2
- ADAM15 | c.1972C>T p.R658* | Nonsense Mutation (SNP) | VAF 79/269 reads (29%) | catalogued as rs755490535, COSV55125843; called by muse, mutect2, varscan2
- ADAM17 | c.2168C>T p.S723L | Missense Mutation (SNP) | VAF 84/248 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV60398060; called by muse, mutect2, varscan2
- ADAM18 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 73/239 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as rs374296414; called by muse, mutect2, varscan2
- ADAM18 | c.665T>G p.F222C | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV55845371; called by muse, mutect2, varscan2
- ADAM19 | c.1944C>A p.F648L | Missense Mutation (SNP) | VAF 71/211 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.635); catalogued as COSV57425095; called by muse, mutect2, varscan2
- ADAM19 | c.1244G>T p.G415V | Missense Mutation (SNP) | VAF 211/702 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV57425123; called by muse, mutect2, varscan2
- ADAM2 | c.772C>A p.L258I | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV55860152; called by muse, mutect2, varscan2
- ADAM21 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV50789964; called by muse, mutect2, varscan2
- ADAM21 | c.902dup p.N301Kfs*21 | Frame Shift Ins (INS) | VAF 27/138 reads (20%) | catalogued as rs1445245525; called by mutect2, pindel, varscan2
- ADAM22 | c.2441G>T p.R814M | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55972647; called by muse, mutect2, varscan2
- ADAM29 | c.647G>T p.R216M | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV63661856; called by muse, mutect2, varscan2
- ADAM29 | c.1140G>T p.E380D | Missense Mutation (SNP) | VAF 136/381 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV100822291, COSV63661862; called by muse, mutect2, varscan2
- ADAM32 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 85/254 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.551); catalogued as rs1393044548, COSV65948041; called by muse, mutect2, varscan2
- ADAM32 | c.1934C>T p.S645L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.031); catalogued as rs757189886, COSV65948045; called by muse, mutect2, varscan2
- ADAM7 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 44/201 reads (22%) | catalogued as COSV51536958, COSV51541184; called by muse, varscan2
- ADAM7 | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99444917; called by muse, varscan2
- ADAMTS12 | c.198T>A p.F66L | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV61258427; called by muse, mutect2, varscan2
- ADAMTS15 | c.2350C>A p.L784I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100143902, COSV54504066; called by muse, mutect2, varscan2
- ADAMTS16 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.425); catalogued as COSV56982827, COSV56985252; called by muse, mutect2, varscan2
- ADAMTS17 | c.1631G>A p.G544E | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51475691; called by muse, mutect2, varscan2
- ADAMTS18 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.322); catalogued as rs779170683, COSV51399738; called by muse, mutect2
- ADAMTS2 | c.2533G>A p.D845N | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs76488852, COSV99281325; called by muse, mutect2, varscan2
- ADAMTS20 | c.4295C>A p.S1432Y | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV67129159; called by muse, mutect2, varscan2
- ADAMTS20 | c.2378G>T p.R793I | Missense Mutation (SNP) | VAF 73/247 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); catalogued as COSV67129165; called by muse, mutect2, varscan2
- ADAMTS20 | c.1271T>G p.V424G | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV101240220; called by muse, mutect2
- ADAMTS20 | c.737G>T p.R246I | Missense Mutation (SNP) | VAF 164/499 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.673); catalogued as COSV67129169; called by muse, mutect2, varscan2
- ADAMTS3 | c.1691C>A p.S564Y | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54387751, COSV54403101; called by muse, mutect2, varscan2
- ADAMTS3 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 82/322 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54387764; called by muse, varscan2
- ADAMTS3 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 72/264 reads (27%) | catalogued as COSV54387776; called by muse, varscan2
- ADAMTS4 | c.2007G>T p.K669N | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.05); catalogued as COSV63489569; called by muse, mutect2, varscan2
- ADAMTS5 | c.2559G>T p.K853N | Missense Mutation (SNP) | VAF 86/249 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs921502863, COSV53177117; called by muse, mutect2, varscan2
- ADAMTS5 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755042708, COSV53177133; called by muse, mutect2, varscan2
- ADAMTS9 | c.3250G>T p.D1084Y | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV55777379; called by muse, mutect2, varscan2
- ADAMTS9 | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs766944266, COSV55777384; called by muse, varscan2
- ADAMTSL1 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52811202; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2653G>A p.D885N | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs561084765; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4754G>T p.R1585I | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV54440819; called by muse, mutect2, varscan2
- ADAMTSL3 | c.5027C>A p.S1676Y | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV54440826; called by muse, mutect2, varscan2
- ADARB2 | c.1388C>T p.S463L | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761776908, COSV67215893; called by muse, mutect2, varscan2
- ADCK1 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 74/207 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs140603078; called by muse, mutect2, varscan2
- ADCY1 | c.2914G>A p.D972N | Missense Mutation (SNP) | VAF 159/447 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0.024); catalogued as rs767943820, COSV52032005; called by muse, mutect2, varscan2
- ADCY10 | c.2582T>C p.L861P | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63239278; called by muse, varscan2
- ADCY2 | c.2796C>A p.F932L | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV57864252, COSV57883513; called by muse, varscan2
- ADCY4 | c.3188A>G p.N1063S | Missense Mutation (SNP) | VAF 143/438 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV60252904; called by muse, mutect2, varscan2
- ADCY4 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.059); catalogued as rs79766112; called by muse, mutect2, varscan2
- ADCY8 | c.2204C>A p.S735Y | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.735); catalogued as COSV53901145; called by muse, mutect2, varscan2
- ADCY9 | c.3967C>T p.R1323* | Nonsense Mutation (SNP) | VAF 140/445 reads (31%) | catalogued as rs1256363458, COSV53572956, COSV53573258; called by muse, mutect2, varscan2
- ADCYAP1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52485931; called by muse, mutect2, varscan2
- ADD3 | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV53321279; called by muse, mutect2, varscan2
- ADD3 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs767558945, COSV53321083; called by muse, mutect2, varscan2
- ADGRA3 | c.2543G>A p.R848Q | Missense Mutation (SNP) | VAF 186/555 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs966886838, COSV51560619; called by muse, mutect2, varscan2
- ADGRA3 | c.1205G>T p.R402I | Missense Mutation (SNP) | VAF 72/257 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV51561257; called by muse, mutect2, varscan2
- ADGRA3 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51561075; called by muse, mutect2, varscan2
- ADGRB1 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV60093665; called by muse, mutect2, varscan2
- ADGRB2 | c.4646C>A p.S1549Y (on ENST00000373658 / NM_001364857.2; = p.S1548Y on NM_001294335.2) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as COSV57071765; called by muse, mutect2, varscan2
- ADGRB3 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV65382494; called by muse, mutect2, varscan2
- ADGRB3 | c.1910C>A p.P637H | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65388673; called by muse, mutect2, varscan2
- ADGRB3 | c.4232C>A p.S1411Y | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53235619; called by muse, mutect2, varscan2
- ADGRB3 | c.4334T>G p.F1445C | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53238861; called by muse, mutect2, varscan2
- ADGRD1 | c.1476A>G p.T492= | Splice Region (SNP) | VAF 42/135 reads (31%) | catalogued as COSV55441255; called by muse, mutect2, varscan2
- ADGRE1 | c.760A>G p.N254D | Missense Mutation (SNP) | VAF 115/320 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.761); catalogued as rs1374665161, COSV51673630; called by muse, mutect2, varscan2
- ADGRE1 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 82/235 reads (35%) | catalogued as COSV51671532, COSV51672387; called by muse, mutect2, varscan2
- ADGRE1 | c.1661G>A p.S554N | Missense Mutation (SNP) | VAF 83/249 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs941392036, COSV51673647; called by muse, mutect2, varscan2
- ADGRE1 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs1194991100, COSV51672107; called by muse, mutect2, varscan2
- ADGRE2 | c.1593G>A p.E531= | Splice Region (SNP) | VAF 59/146 reads (40%) | catalogued as rs753358915, COSV59692430; called by muse, mutect2, varscan2
- ADGRE2 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.074); catalogued as rs764868326, COSV59692435; called by muse, mutect2, varscan2
- ADGRE5 | c.834C>A p.F278L (on ENST00000242786 / NM_078481.4; = p.F185L on NM_001784.5) | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV54409191, COSV54416782; called by muse, mutect2, varscan2
- ADGRF3 | c.1270A>G p.I424V (on ENST00000311519 / NM_001145168.1; = p.I225V on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV61049411; called by muse, mutect2, varscan2
- ADGRF3 | c.454G>A p.A152T (on ENST00000311519 / NM_001145168.1; = p.A93T on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/212 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as COSV61049423; called by muse, mutect2, varscan2
- ADGRF4 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs772794418, COSV51949756; called by muse, mutect2, varscan2
- ADGRF5 | c.954A>C p.R318S | Missense Mutation (SNP) | VAF 88/299 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV51931536; called by muse, varscan2
- ADGRG4 | c.697A>G p.N233D | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV54952058; called by muse, mutect2, varscan2
- ADGRG4 | c.1457G>T p.R486I | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV54952064, COSV54958415; called by muse, mutect2, varscan2
- ADGRG4 | c.4474C>T p.P1492S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV54952076, COSV54961397; called by muse, mutect2, varscan2
- ADGRG4 | c.4475C>A p.P1492Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV54952084, COSV54962014; called by muse, mutect2, varscan2
- ADGRG4 | c.5831G>T p.G1944V | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV54952094; called by muse, mutect2, varscan2
- ADGRG4 | c.6599T>G p.V2200G | Missense Mutation (SNP) | VAF 88/270 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV54952103; called by muse, mutect2, varscan2
- ADGRG6 | c.76T>G p.L26V | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.023); catalogued as COSV51588727; called by muse, varscan2
- ADGRG6 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs753293070, COSV51588750; called by muse, mutect2, varscan2
- ADGRL2 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 55/141 reads (39%) | catalogued as COSV54658658; called by muse, mutect2, varscan2
- ADGRL3 | c.522dup p.P175Sfs*9 (on ENST00000506720 / NM_001322402.2; = p.P107Sfs*9 on NM_015236.6) | Frame Shift Ins (INS) | VAF 57/214 reads (27%) | catalogued as rs1561047192; called by pindel, varscan2
- ADGRL3 | c.3002G>A p.R1001Q (on ENST00000506720 / NM_001322402.2; = p.R933Q on NM_015236.6) | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.888); catalogued as rs370040630; called by muse, mutect2
- ADGRL3 | c.3542C>A p.S1181Y (on ENST00000506720 / NM_001322402.2; = p.S1113Y on NM_015236.6) | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1182581433, COSV72230007; called by muse, mutect2, varscan2
- ADGRL4 | c.911G>T p.S304I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV66060270; called by muse, mutect2, varscan2
- ADGRV1 | c.1523T>G p.I508S | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101316424; called by muse, mutect2
- ADGRV1 | c.2996G>T p.R999I | Missense Mutation (SNP) | VAF 115/357 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV101315729, COSV67981041; called by muse, mutect2, varscan2
- ADGRV1 | c.8104G>A p.A2702T | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67981050; called by muse, varscan2
- ADGRV1 | c.17014G>T p.E5672* | Nonsense Mutation (SNP) | VAF 35/109 reads (32%) | catalogued as COSV67981054; called by muse, mutect2, varscan2
- ADGRV1 | c.17063G>A p.R5688Q | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs374682222; called by muse, mutect2, varscan2
- ADH1C | c.57G>T p.K19N | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs748223863, COSV72463413; called by muse, mutect2, varscan2
- ADH6 | c.964+1G>A p.X322_splice | Splice Site (SNP) | VAF 80/251 reads (32%) | catalogued as COSV52955519; called by muse, mutect2, varscan2
- ADH6 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756863693, COSV52955529; called by muse, varscan2
- ADHFE1 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); catalogued as rs368995778; called by muse, mutect2, varscan2
- ADK | c.896T>G p.F299C (on ENST00000286621; = p.F282C on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/256 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV54201678; called by muse, mutect2, varscan2
- ADNP | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 117/366 reads (32%) | catalogued as COSV62424720; called by muse, mutect2, varscan2
- ADNP2 | c.2437G>A p.D813N | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs766821105, COSV51537235; called by muse, mutect2, varscan2
- ADORA2B | c.443A>G p.D148G | Missense Mutation (SNP) | VAF 95/256 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV58481642; called by muse, mutect2, varscan2
- ADRA2A | c.494T>C p.I165T | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54527235; called by muse, mutect2, varscan2
- ADRA2C | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57467007; called by muse, mutect2, varscan2
- ADSS1 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV58272667; called by muse, mutect2, varscan2
- AFAP1L1 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1413854340, COSV57044407, COSV57044996; called by muse, mutect2, varscan2
- AFDN | c.607T>G p.Y203D | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV60040491; called by muse, mutect2, varscan2
- AFDN | c.1593G>T p.E531D | Missense Mutation (SNP) | VAF 129/446 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); catalogued as COSV60040523; called by muse, mutect2, varscan2
- AFF1 | c.3084C>A p.F1028L | Missense Mutation (SNP) | VAF 95/345 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV57118177; called by muse, mutect2, varscan2
- AFF2 | c.419C>A p.S140Y | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60657786; called by muse, mutect2, varscan2
- AFG3L2 | c.2140G>A p.A714T | Missense Mutation (SNP) | VAF 127/354 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs768153900, COSV52313348; called by muse, mutect2, varscan2
- AFP | c.368A>C p.N123T | Missense Mutation (SNP) | VAF 72/220 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV56924422; called by muse, mutect2, varscan2
- AGBL1 | c.1750T>C p.W584R | Missense Mutation (SNP) | VAF 110/324 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs1413507410, COSV66852896; called by muse, varscan2
- AGBL2 | c.1654C>A p.L552M | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV54090837; called by muse, mutect2, varscan2
- AGBL4 | c.1002G>T p.M334I | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV61891330; called by muse, mutect2, varscan2
- AGGF1 | c.314A>C p.D105A | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57228247; called by muse, varscan2
- AGGF1 | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as rs762299495, COSV57228257; called by muse, mutect2, varscan2
- AGGF1 | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs747964895, COSV57228264; called by muse, mutect2, varscan2
- AGMAT | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768762536, COSV65435721; called by muse, mutect2, varscan2
- AGMO | c.855C>A p.F285L | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV61108565, COSV61113252; called by muse, mutect2, varscan2
- AGO2 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs773613021, COSV99596319; called by muse, mutect2, varscan2
- AGO3 | c.549C>A p.F183L | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV55792100; called by muse, mutect2, varscan2
- AGO4 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 85/309 reads (28%) | catalogued as COSV64616661; called by muse, mutect2, varscan2
- AGPAT5 | c.258T>G p.N86K | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as COSV53446115; called by muse, mutect2, varscan2
- AGPAT5 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 47/159 reads (30%) | catalogued as rs752941173, COSV53446129; called by muse, mutect2, varscan2
- AGTPBP1 | c.2728C>T p.R910C (on ENST00000357081 / NM_001330701.2; = p.R870C on NM_015239.2) | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61268816; called by muse, mutect2, varscan2
- AGTR1 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV62557616; called by muse, mutect2, varscan2
- AHCTF1 | c.2928T>G p.F976L (on ENST00000366508; = p.F950L on NM_015446.5) | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58247552; called by muse, mutect2, varscan2
- AHI1 | c.3408A>T p.K1136N | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV55624726; called by muse, mutect2, varscan2
- AHNAK | c.10372C>A p.L3458I | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as rs760472621, COSV57207800; called by muse, mutect2, varscan2
- AHNAK | c.9659C>A p.S3220* | Nonsense Mutation (SNP) | VAF 89/374 reads (24%) | catalogued as COSV57207816; called by muse, mutect2, varscan2
- AHNAK | c.9196A>G p.N3066D | Missense Mutation (SNP) | VAF 90/369 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV57207829; called by muse, mutect2, varscan2
- AHNAK | c.7634A>G p.K2545R | Missense Mutation (SNP) | VAF 151/458 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.779); catalogued as COSV57207843; called by muse, mutect2, varscan2
- AHNAK2 | c.16468C>T p.L5490F | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.09); catalogued as COSV60911036, COSV60924087; called by muse, mutect2, varscan2
- AHNAK2 | c.13929G>T p.K4643N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs561262101, COSV60911048; called by muse, varscan2
- AHNAK2 | c.13888G>T p.G4630* | Nonsense Mutation (SNP) | VAF 23/69 reads (33%) | catalogued as COSV60910460, COSV60911056; called by muse, varscan2
- AHNAK2 | c.8703G>A p.M2901I | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs1476762704, COSV60908763; called by muse, mutect2, varscan2
- AHNAK2 | c.1963A>T p.K655* | Nonsense Mutation (SNP) | VAF 238/621 reads (38%) | catalogued as COSV100317863, COSV60911076; called by muse, mutect2, varscan2
- AHR | c.314A>C p.N105T | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV54122352; called by muse, mutect2, varscan2
- AIFM1 | c.606-1G>T p.X202_splice | Splice Site (SNP) | VAF 96/363 reads (26%) | catalogued as COSV54853508; called by muse, varscan2
- AIFM1 | c.411T>G p.I137M | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54853529; called by muse, mutect2, varscan2
- AIM2 | c.958A>C p.N320H | Missense Mutation (SNP) | VAF 168/480 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.101); catalogued as COSV63698930; called by muse, varscan2
- AIPL1 | c.277-1G>A p.X93_splice | Splice Site (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100006180; called by muse, mutect2
- AK4 | c.558-1G>T p.X186_splice | Splice Site (SNP) | VAF 87/305 reads (29%) | catalogued as COSV59196649; called by muse, mutect2, varscan2
- AK5 | c.571G>T p.E191* (on ENST00000354567 / NM_174858.3; = p.E165* on NM_012093.4) | Nonsense Mutation (SNP) | VAF 58/195 reads (30%) | catalogued as COSV58355085; called by muse, mutect2, varscan2
- AK7 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 77/272 reads (28%) | catalogued as rs777849703, COSV50869905; called by muse, mutect2, varscan2
- AK9 | c.5604T>G p.S1868R | Missense Mutation (SNP) | VAF 111/324 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs900186003, COSV69849948; called by muse, mutect2, varscan2
- AKAP10 | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV56730528; called by muse, mutect2, varscan2
- AKAP10 | c.1179C>A p.F393L | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV56730536; called by muse, mutect2, varscan2
- AKAP12 | c.2002G>T p.E668* | Nonsense Mutation (SNP) | VAF 65/193 reads (34%) | catalogued as COSV53571659; called by muse, mutect2, varscan2
- AKAP12 | c.2448G>T p.K816N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53571672; called by muse, mutect2, varscan2
- AKAP12 | c.5327A>C p.K1776T | Missense Mutation (SNP) | VAF 109/307 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV53571683; called by muse, mutect2, varscan2
- AKAP3 | c.1799A>G p.N600S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV57415127; called by muse, mutect2, varscan2
- AKAP4 | c.904C>A p.L302I | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as COSV62073977; called by muse, mutect2, varscan2
- AKAP6 | c.1890C>A p.Y630* | Nonsense Mutation (SNP) | VAF 53/173 reads (31%) | catalogued as COSV55208477; called by muse, mutect2, varscan2
- AKAP6 | c.4955G>A p.R1652Q | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763532229, COSV55208487; called by muse, mutect2, varscan2
- AKAP6 | c.5397G>T p.K1799N | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55208509, COSV55228105; called by muse, mutect2, varscan2
- AKAP9 | c.68G>T p.R23I | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62341659; called by muse, mutect2, varscan2
- AKAP9 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 58/166 reads (35%) | catalogued as COSV62341674; called by muse, mutect2, varscan2
- AKAP9 | c.2978G>A p.R993K | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs777988488, COSV62341688; called by muse, mutect2, varscan2
- AKAP9 | c.4024G>T p.E1342* | Nonsense Mutation (SNP) | VAF 39/110 reads (35%) | catalogued as COSV62341704; called by muse, mutect2, varscan2
- AKAP9 | c.6016G>T p.E2006* (on ENST00000359028; = p.E1974* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 44/128 reads (34%) | catalogued as COSV62341719; called by muse, mutect2, varscan2
- AKAP9 | c.6077T>G p.L2026* (on ENST00000359028; = p.L1994* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 35/105 reads (33%) | catalogued as COSV62341731; called by muse, mutect2, varscan2
- AKAP9 | c.9994C>T p.R3332* (on ENST00000359028; = p.R3308* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 61/201 reads (30%) | catalogued as rs771217988, COSV62341755; called by muse, mutect2, varscan2
- AKNA | c.1703C>A p.S568Y | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56311715; called by muse, mutect2, varscan2
- AKNAD1 | c.2467G>A p.D823N | Missense Mutation (SNP) | VAF 167/471 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64171577; called by muse, mutect2, varscan2
- AKR1C1 | c.42C>A p.H14Q | Missense Mutation (SNP) | VAF 162/504 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV66498809; called by muse, mutect2, varscan2
- AKR1C2 | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 142/602 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV66332607; called by muse, mutect2, varscan2
- AKT2 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs768703735, COSV60907985; called by muse, mutect2, varscan2
- AL133500.1 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated, low confidence (0.14); catalogued as COSV55744401; called by muse, mutect2, varscan2
- AL592490.1 | c.2566C>A p.L856I | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV69425298; called by muse, mutect2, varscan2
- AL713999.2 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 155/462 reads (34%) | catalogued as COSV55278423, COSV99826137; called by muse, mutect2, varscan2
- ALAS1 | c.1764G>T p.E588D | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV59627266; called by muse, mutect2, varscan2
- ALDH1A1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs778276187, COSV52789879; called by muse, mutect2, varscan2
- ALDH1A2 | c.1410-1G>T p.X470_splice | Splice Site (SNP) | VAF 66/196 reads (34%) | catalogued as COSV51078914; called by muse, mutect2, varscan2
- ALDH1A2 | c.1110G>T p.K370N | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV51078938; called by muse, mutect2, varscan2
- ALDH1A2 | c.518G>A p.R173K | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as COSV51078962, COSV51080994; called by muse, mutect2, varscan2
- ALDH1A2 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 73/181 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as rs201593015; called by muse, mutect2, varscan2
- ALDH1L1 | c.1311G>T p.K437N | Missense Mutation (SNP) | VAF 88/262 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV56412103; called by muse, varscan2
- ALDH3B1 | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99142053; called by muse, mutect2, varscan2
- ALDH3B2 | c.1065G>T p.E355D | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV62427795; called by muse, mutect2, varscan2
- ALG10 | c.436T>G p.F146V | Missense Mutation (SNP) | VAF 165/397 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56792053; called by muse, varscan2
- ALG10 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 138/459 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762214045, COSV56791818; called by muse, mutect2, varscan2
- ALG11 | c.1357C>A p.L453I | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.871); catalogued as rs199616330, COSV73000610; called by muse, mutect2, varscan2
- ALG13 | c.3323C>A p.S1108Y | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV52636522; called by muse, mutect2, varscan2
- ALG6 | c.125G>T p.R42I | Missense Mutation (SNP) | VAF 165/476 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54763879; called by muse, mutect2, varscan2
- ALK | c.3923C>A p.S1308Y | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66561969; called by muse, mutect2, varscan2
- ALK | c.1458C>A p.F486L | Missense Mutation (SNP) | VAF 100/306 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV66561981, COSV66589063; called by muse, mutect2, varscan2
- ALKBH6 | c.71A>G p.Y24C (on ENST00000252984 / NM_001297701.2; = p.Y52C on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/304 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV53324238; called by muse, mutect2, varscan2
- ALLC | c.300T>C p.D100= | Splice Region (SNP) | VAF 48/128 reads (38%) | catalogued as rs768076246, COSV52993625; called by muse, mutect2, varscan2
- ALLC | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as COSV52993634; called by muse, mutect2, varscan2
- ALMS1 | c.4218G>T p.K1406N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.242); catalogued as COSV52505920; called by muse, mutect2, varscan2
- ALMS1 | c.8804C>T p.A2935V | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV52505945; called by muse, mutect2, varscan2
- ALMS1 | c.11204C>T p.S3735L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); catalogued as rs367877017, CM074702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALMS1 | c.12320A>G p.N4107S | Missense Mutation (SNP) | VAF 169/511 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV52505963; called by muse, mutect2, varscan2
- ALOX15 | c.1239T>G p.I413M | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV53396703; called by muse, mutect2, varscan2
- ALOXE3 | c.1892A>G p.E631G | Missense Mutation (SNP) | VAF 149/476 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV59074616; called by muse, mutect2, varscan2
- ALPK1 | c.3284T>G p.F1095C | Missense Mutation (SNP) | VAF 100/249 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51583292; called by muse, mutect2, varscan2
- ALPK2 | c.5147A>C p.E1716A | Missense Mutation (SNP) | VAF 89/272 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV64491401; called by muse, mutect2, varscan2
- ALPK2 | c.3382G>T p.E1128* | Nonsense Mutation (SNP) | VAF 54/162 reads (33%) | catalogued as COSV64491410; called by muse, mutect2, varscan2
- ALPK2 | c.2561C>A p.S854Y | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.862); catalogued as COSV64491420; called by muse, mutect2, varscan2
- ALPK2 | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1412899048, COSV64491432; called by muse, mutect2, varscan2
- ALPK2 | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as rs766605419, COSV64491438; called by muse, mutect2, varscan2
- ALS2CL | c.1389G>A p.W463* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV59670754; called by muse, mutect2, varscan2
- AMBN | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV59825108, COSV59825190, COSV59825299; called by muse, varscan2
- AMD1 | c.396A>C p.E132D | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as COSV64387106; called by muse, mutect2, varscan2
- AMDHD1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763890532, COSV57138051; called by muse, mutect2, varscan2
- AMER1 | c.1617C>A p.F539L | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV57656876; called by muse, mutect2, varscan2
- AMER1 | c.456G>T p.E152D | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as COSV57656892, COSV57658933; called by muse, mutect2, varscan2
- AMER2 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.759); catalogued as rs1219431469, COSV63436647; called by muse, mutect2, varscan2
- AMER3 | c.19A>C p.K7Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV58465740; called by muse, mutect2, varscan2
- AMER3 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV58467060; called by muse, mutect2
- AMER3 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1381313687, COSV58465747; called by muse, mutect2, varscan2
- AMFR | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as COSV51920329; called by muse, mutect2, varscan2
- AMFR | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 67/242 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV51920340; called by muse, varscan2
- AMFR | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 76/242 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV51920352; called by muse, varscan2
- AMIGO2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV56973669; called by muse, mutect2, varscan2
- AMOTL1 | c.4T>C p.W2R | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV54414697; called by muse, mutect2, varscan2
- AMOTL1 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 81/258 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV54414703; called by muse, mutect2, varscan2
- AMOTL1 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV58565647; called by muse, varscan2
- AMPD1 | c.1324-2A>G p.X442_splice | Splice Site (SNP) | VAF 21/76 reads (28%) | catalogued as COSV62415435; called by muse, mutect2, varscan2
- AMPH | c.764T>C p.L255P | Missense Mutation (SNP) | VAF 102/309 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57737205; called by muse, mutect2, varscan2
- AMPH | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 79/304 reads (26%) | catalogued as COSV57737224; called by muse, mutect2, varscan2
- ANAPC1 | c.3278A>C p.H1093P | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as COSV61974882; called by muse, varscan2
- ANAPC1 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as rs567800751, COSV61974886; called by muse, mutect2, varscan2
- ANAPC15 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.04); catalogued as rs982888986, COSV56191427; called by muse, mutect2, varscan2
- ANAPC4 | c.481T>C p.S161P | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.593); catalogued as rs1314890906, COSV59543361; called by muse, mutect2, varscan2
- ANAPC7 | c.358A>C p.T120P | Missense Mutation (SNP) | VAF 90/250 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.282); catalogued as COSV71443764; called by muse, mutect2, varscan2
- ANGEL1 | c.1508-1G>T p.X503_splice | Splice Site (SNP) | VAF 19/80 reads (24%) | catalogued as COSV51872252; called by muse, mutect2, varscan2
- ANGPT2 | c.318G>T p.K106N | Missense Mutation (SNP) | VAF 180/503 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV57335549; called by muse, mutect2, varscan2
- ANK1 | c.2896G>A p.A966T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV55874926; called by muse, mutect2, varscan2
- ANK1 | c.913G>A p.G305S | Missense Mutation (SNP) | VAF 80/260 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs750789310, COSV55876822; called by muse, mutect2, varscan2
- ANK2 | c.861T>G p.D287E | Missense Mutation (SNP) | VAF 118/331 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV52152137; called by muse, mutect2, varscan2
- ANK2 | c.4280G>A p.R1427Q | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754722115, COSV52144785; called by muse, varscan2
- ANK2 | c.4408G>A p.D1470N | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.167); catalogued as rs564648496, COSV52147187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.10631C>T p.P3544L | Missense Mutation (SNP) | VAF 89/244 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as COSV55049451; called by muse, mutect2, varscan2
- ANK3 | c.8201C>A p.S2734Y | Missense Mutation (SNP) | VAF 97/269 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV55049474; called by muse, mutect2, varscan2
- ANK3 | c.7136A>G p.K2379R | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV55049482; called by muse, mutect2, varscan2
- ANK3 | c.3521G>T p.R1174I (on ENST00000280772 / NM_001320874.2; = p.R308I on NM_001149.3) | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1285570735, COSV55049500; called by muse, mutect2, varscan2
- ANKAR | c.922G>T p.D308Y | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV55610757; called by muse, varscan2
- ANKAR | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs368009564; called by muse, varscan2
- ANKAR | c.3065G>C p.S1022T | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV55610803; called by muse, mutect2, varscan2
- ANKDD1A | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs553148491, COSV60353072; called by muse, mutect2, varscan2
- ANKFY1 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as rs903431173, COSV58915656; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV51843107; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4448C>T p.S1483L | Missense Mutation (SNP) | VAF 131/434 reads (30%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs775180361, COSV51843131; called by muse, mutect2, varscan2
- ANKLE1 | c.1274G>A p.R425Q (on ENST00000394458; = p.R371Q on NM_152363.6) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs768659445, COSV63920150; called by muse, mutect2, varscan2
- ANKLE2 | c.2779C>T p.R927C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs774240785, COSV63294636; called by muse, mutect2, varscan2
- ANKRD12 | c.2194G>T p.D732Y | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV50820804; called by muse, mutect2, varscan2
- ANKRD12 | c.3536C>A p.S1179Y | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0.254); catalogued as COSV100042100, COSV50820822; called by muse, mutect2, varscan2
- ANKRD13B | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs546096254, COSV67473573; called by muse, mutect2, varscan2
- ANKRD17 | c.5382G>T p.K1794N | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as COSV58217543, COSV58224110; called by muse, mutect2, varscan2
- ANKRD17 | c.2479G>T p.E827* | Nonsense Mutation (SNP) | VAF 128/372 reads (34%) | catalogued as COSV58217567; called by muse, mutect2, varscan2
- ANKRD24 | c.1822G>T p.E608* | Nonsense Mutation (SNP) | VAF 62/186 reads (33%) | catalogued as COSV53667361, COSV53668764; called by muse, mutect2, varscan2
- ANKRD27 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 83/255 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555830097, COSV60129915; called by muse, mutect2, varscan2
- ANKRD27 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as rs766519033, COSV60128664; called by muse, varscan2
- ANKRD34B | c.1484A>C p.K495T | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV58613624; called by muse, mutect2, varscan2
- ANKRD35 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 151/500 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.149); catalogued as COSV62909902; called by muse, mutect2, varscan2
- ANKRD45 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 85/226 reads (38%) | catalogued as COSV60960494; called by muse, mutect2, varscan2
- ANKRD49 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as rs767511021, COSV57060117; called by muse, mutect2
- ANKRD50 | c.3637T>C p.S1213P | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV72385296; called by muse, varscan2
- ANKRD50 | c.3560C>A p.S1187* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as rs1289108292, COSV101539035; called by muse, varscan2
- ANKRD50 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1030118161, COSV72385112; called by muse, mutect2, varscan2
- ANKRD55 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 48/124 reads (39%) | catalogued as COSV61945050; called by muse, mutect2, varscan2
- ANKS1B | c.3661C>T p.R1221C (on ENST00000547776 / NM_152788.4; = p.R387C on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 166/514 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs867103953, COSV59116554; called by muse, varscan2
- ANKS1B | c.2389G>T p.E797* | Nonsense Mutation (SNP) | VAF 126/419 reads (30%) | catalogued as COSV61339092, COSV61341411; called by muse, mutect2, varscan2
- ANKZF1 | c.176G>T p.R59I | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as COSV55475859; called by muse, mutect2, varscan2
- ANO10 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 53/165 reads (32%) | catalogued as COSV52729491; called by muse, mutect2, varscan2
- ANO2 | c.2587G>T p.E863* (on ENST00000356134 / NM_001278597.3; = p.E867* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 74/206 reads (36%) | catalogued as COSV59007397, COSV59012960; called by muse, mutect2, varscan2
- ANO2 | c.2091G>A p.P697= (on ENST00000356134 / NM_001278597.3; = p.P701= on NM_001278596.3) | Splice Region (SNP) | VAF 54/201 reads (27%) | catalogued as COSV59012988; called by muse, mutect2, varscan2
- ANO3 | c.539G>T p.R180I | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56784977; called by muse, mutect2, varscan2
- ANO3 | c.1810T>G p.F604V | Missense Mutation (SNP) | VAF 148/447 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV56784988; called by muse, mutect2, varscan2
- ANO3 | c.2863G>T p.E955* | Nonsense Mutation (SNP) | VAF 53/108 reads (49%) | catalogued as COSV56784998; called by muse, mutect2, varscan2
- ANO5 | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 97/295 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV61083312; called by muse, varscan2
- ANO5 | c.696G>T p.K232N | Missense Mutation (SNP) | VAF 92/283 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); catalogued as COSV61083318; called by muse, varscan2
- ANO5 | c.2072C>A p.P691H | Missense Mutation (SNP) | VAF 129/399 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61083322; called by muse, mutect2, varscan2
- ANO6 | c.1727T>G p.F576C | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57658732; called by muse, mutect2, varscan2
- ANO8 | c.884C>T p.S295L | Missense Mutation (SNP) | VAF 90/250 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV50174155; called by muse, mutect2, varscan2
- ANO9 | c.1928C>T p.T643I | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); catalogued as rs1172740439, COSV60382824; called by muse, mutect2, varscan2
- ANP32E | c.124A>T p.K42* | Nonsense Mutation (SNP) | VAF 78/250 reads (31%) | catalogued as COSV58481583; called by muse, mutect2, varscan2
- ANTXR1 | c.1178G>T p.R393I | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58010920; called by muse, mutect2, varscan2
- ANXA6 | c.1508C>A p.S503Y | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62905891; called by muse, mutect2, varscan2
- ANXA6 | c.942G>T p.K314N | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62905896, COSV62908175; called by muse, mutect2, varscan2
- AOAH | c.638T>C p.V213A | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV51737686; called by muse, mutect2, varscan2
- AOC1 | c.1960C>A p.L654I | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV62867598; called by muse, mutect2, varscan2
- AOPEP | c.2180G>A p.R727Q (on ENST00000375315 / NM_001193329.1; = p.R628Q on NM_032823.5) | Missense Mutation (SNP) | VAF 94/229 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs963224133, COSV52987575; called by muse, mutect2, varscan2
- AOX1 | c.860C>A p.S287Y | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.224); catalogued as COSV65980758; called by muse, varscan2
- AOX1 | c.2852G>A p.R951Q | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs142541240, COSV65980091; called by muse, mutect2, varscan2
- AP1AR | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV56768735; called by muse, mutect2, varscan2
- AP1G1 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.08); catalogued as rs376889684, COSV100250587; called by muse, mutect2
- AP1G1 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 102/291 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV55486934; called by muse, mutect2, varscan2
- AP1G2 | c.2206C>T p.R736W | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.539); catalogued as rs753650407, COSV55337656; called by muse, mutect2, varscan2
- AP2B1 | c.1302G>T p.E434D | Missense Mutation (SNP) | VAF 95/325 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV51997936; called by muse, mutect2, varscan2
- AP2M1 | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 61/265 reads (23%) | catalogued as COSV53047489; called by muse, mutect2, varscan2
- AP4B1 | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as rs1471215054, COSV56723946; called by muse, mutect2, varscan2
- AP4B1 | c.1346G>T p.R449I | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV56723958; called by muse, mutect2, varscan2
- AP4E1 | c.1969C>A p.L657I | Missense Mutation (SNP) | VAF 78/253 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV55915809; called by muse, mutect2, varscan2
- AP4E1 | c.2121G>T p.K707N | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as rs1375543680, COSV55915820; called by muse, varscan2
- AP4E1 | c.2205G>T p.E735D | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV55915832; called by muse, varscan2
- AP4E1 | c.3085G>T p.D1029Y | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55915846; called by muse, mutect2, varscan2
- AP4M1 | c.158G>A p.G53D | Missense Mutation (SNP) | VAF 165/528 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100385059; called by muse, mutect2, varscan2
- APAF1 | c.1055G>T p.R352I (on ENST00000551964 / NM_181861.2; = p.R341I on NM_001160.3) | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59662575; called by muse, mutect2, varscan2
- APAF1 | c.2305-1G>T p.X769_splice (on ENST00000551964 / NM_181861.2; = p.X758_splice on NM_001160.3) | Splice Site (SNP) | VAF 50/146 reads (34%) | catalogued as COSV59662580; called by muse, mutect2, varscan2
- APBA1 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as rs1374858591, COSV55223712; called by muse, mutect2, varscan2
- APBA1 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.059); catalogued as rs1292218177, COSV55223722, COSV99597310; called by muse, varscan2
- APBA3 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs548949116, COSV57462096; called by muse, mutect2, varscan2
- APBB1IP | c.1248A>G p.I416M | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV66131083; called by muse, mutect2, varscan2
- APBB2 | c.1856C>A p.S619* (on ENST00000295974 / NM_001166050.2; = p.S620* on NM_004307.2) | Nonsense Mutation (SNP) | VAF 40/162 reads (25%) | catalogued as COSV55949327; called by muse, mutect2, varscan2
- APC | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV57333109, COSV57383671, COSV57401345; called by muse, mutect2, varscan2
- APC | c.2174C>T p.A725V | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57333116; called by muse, mutect2, varscan2
- APC | c.3755C>A p.S1252Y | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV57333121; called by muse, mutect2, varscan2
- APC | c.4199C>T p.S1400L | Missense Mutation (SNP) | VAF 74/199 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs267600319, CM995167, COSV57324455, COSV57326621, COSV57333132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.7870A>G p.N2624D | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs550242704, COSV57333155; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC2 | c.1257G>T p.M419I | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99279809; called by muse, mutect2, varscan2
- APCDD1 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.35); catalogued as rs767678347, COSV62372253; called by muse, mutect2, varscan2
- APCS | c.506T>C p.F169S | Missense Mutation (SNP) | VAF 115/379 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1329449773, COSV54817599; called by muse, mutect2, varscan2
- APCS | c.605T>C p.L202P | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54817607; called by muse, mutect2, varscan2
- API5 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 98/283 reads (35%) | catalogued as COSV66632722; called by muse, mutect2, varscan2
- APLF | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs769480335, COSV100377003, COSV58143504; called by muse, mutect2, varscan2
- APOA4 | c.1167G>T p.Q389H | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV63360226; called by muse, mutect2, varscan2
- APOB | c.12835G>T p.E4279* | Nonsense Mutation (SNP) | VAF 50/161 reads (31%) | catalogued as COSV51928518; called by muse, mutect2, varscan2
- APOB | c.11276C>A p.P3759Q | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51928531; called by muse, varscan2
- APOB | c.11230C>A p.L3744I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.297); catalogued as COSV51928541; called by muse, varscan2
- APOB | c.10921T>G p.S3641A | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV51928558; called by muse, varscan2
- APOB | c.10825T>A p.S3609T | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as rs1060500239, COSV51928571; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.7850T>G p.F2617C | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51928585; called by muse, mutect2, varscan2
- APOB | c.5416C>A p.L1806M | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV51928602; called by muse, mutect2, varscan2
- APOB | c.4796G>A p.R1599H | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as rs746414462, COSV51927055; ClinVar: likely benign; called by muse, mutect2, varscan2
- APOB | c.4250C>T p.T1417M | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.147); catalogued as rs200321839, COSV51928643; called by muse, mutect2, varscan2
- APOB | c.2911C>A p.P971T | Missense Mutation (SNP) | VAF 95/267 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51928665; called by muse, mutect2, varscan2
- APOB | c.1658C>A p.S553Y | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV51928677, COSV51949880; called by muse, mutect2, varscan2
- APOBEC3F | c.870C>A p.F290L | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57910060; called by muse, mutect2, varscan2
- APOBR | c.843G>T p.E281D | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV60489460; called by muse, mutect2, varscan2
- APOL5 | c.780G>T p.K260N | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as COSV50766491, COSV50768685; called by muse, mutect2, varscan2
- APOL6 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV68749413; called by muse, mutect2, varscan2
- APP | c.1263G>T p.K421N | Missense Mutation (SNP) | VAF 154/454 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV60996183; called by muse, mutect2, varscan2
- APPBP2 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 103/347 reads (30%) | catalogued as rs772369679, COSV50026190; called by muse, mutect2, varscan2
- APPL1 | c.1699C>A p.P567T | Missense Mutation (SNP) | VAF 70/267 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.477); catalogued as COSV55700181; called by muse, mutect2, varscan2
- AQP1 | c.54C>A p.F18L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); catalogued as COSV61266249, COSV61266345; called by muse, mutect2, varscan2
- AQP7 | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as COSV53010295; called by muse, mutect2, varscan2
- AQP8 | c.401A>T p.E134V | Missense Mutation (SNP) | VAF 90/303 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.34); catalogued as COSV54844570; called by muse, mutect2, varscan2
- AQP9 | c.90C>A p.F30L | Missense Mutation (SNP) | VAF 72/280 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV54967982; called by muse, mutect2, varscan2
- AQR | c.2065G>A p.D689N | Missense Mutation (SNP) | VAF 80/277 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.399); catalogued as rs762754535, COSV50030780; called by muse, mutect2, varscan2
- AR | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV65954328, COSV65964204; called by muse, mutect2, varscan2
- ARAF | c.1337G>A p.G446D | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51691840; called by muse, mutect2, varscan2
- ARAP2 | c.3413T>G p.F1138C | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58284308; called by muse, mutect2, varscan2
- ARAP2 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 38/107 reads (36%) | catalogued as COSV58282405; called by muse, mutect2, varscan2
- ARAP3 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs536292464, COSV53349505; called by muse, mutect2, varscan2
- ARAP3 | c.1003A>C p.T335P | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV53349514; called by muse, mutect2, varscan2
- ARF4 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 68/224 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.95); catalogued as rs747265204, COSV57714761; called by muse, mutect2, varscan2
- ARFGAP3 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV54311120; called by muse, mutect2, varscan2
- ARFGEF1 | c.2626G>T p.E876* | Nonsense Mutation (SNP) | VAF 178/604 reads (29%) | catalogued as COSV51604818; called by muse, varscan2
- ARFGEF2 | c.1475C>A p.S492Y | Missense Mutation (SNP) | VAF 63/211 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64211331, COSV64213467; called by muse, mutect2, varscan2
- ARFGEF2 | c.2404C>T p.R802W | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1390031598, COSV64211335, COSV64213243; called by muse, mutect2, varscan2
- ARFGEF3 | c.1108C>A p.L370I | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV52452911; called by muse, mutect2, varscan2
- ARFGEF3 | c.2056C>T p.R686W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs557965026, COSV52452929; called by muse, mutect2, varscan2
- ARFGEF3 | c.2872G>T p.E958* | Nonsense Mutation (SNP) | VAF 28/133 reads (21%) | catalogued as COSV52452942; called by muse, mutect2, varscan2
- ARHGAP1 | c.1222A>G p.I408V | Missense Mutation (SNP) | VAF 105/359 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1338239627, COSV56318280; called by muse, mutect2, varscan2
- ARHGAP12 | c.2044G>T p.E682* | Nonsense Mutation (SNP) | VAF 55/157 reads (35%) | catalogued as COSV60962163; called by muse, mutect2, varscan2
- ARHGAP12 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 92/366 reads (25%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV60962175; called by muse, mutect2, varscan2
- ARHGAP15 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as COSV54485463; called by muse, mutect2, varscan2
- ARHGAP15 | c.692G>T p.R231I | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs1171768213, COSV54485471; called by muse, mutect2, varscan2
- ARHGAP15 | c.800C>A p.T267N | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV54485477; called by muse, mutect2, varscan2
- ARHGAP17 | c.2300G>T p.G767V (on ENST00000289968 / NM_001006634.3; = p.G689V on NM_018054.6) | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV51505661; called by muse, mutect2, varscan2
- ARHGAP21 | c.5285A>C p.K1762T | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV57603824; called by muse, mutect2, varscan2
- ARHGAP21 | c.4723G>A p.E1575K | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.355); catalogued as rs373404445, COSV100255827; called by muse, mutect2, varscan2
- ARHGAP21 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 91/266 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1436858905, COSV100256243, COSV57603838; called by muse, mutect2, varscan2
- ARHGAP24 | c.437G>T p.R146I (on ENST00000395184 / NM_001025616.3; = p.R53I on NM_031305.3) | Missense Mutation (SNP) | VAF 65/218 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51987770; called by muse, mutect2, varscan2
- ARHGAP26 | c.709A>C p.N237H | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV50825833; called by muse, mutect2, varscan2
- ARHGAP26 | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 33/108 reads (31%) | catalogued as COSV50825842; called by muse, mutect2, varscan2
- ARHGAP26 | c.2231A>G p.D744G | Missense Mutation (SNP) | VAF 134/384 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV50825852; called by muse, mutect2, varscan2
- ARHGAP28 | c.778G>A p.E260K (on ENST00000383472 / NM_001366230.1; = p.E101K on NM_001010000.3) | Missense Mutation (SNP) | VAF 137/393 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as COSV51634106; called by muse, mutect2, varscan2
- ARHGAP28 | c.955-1G>T p.X319_splice (on ENST00000383472 / NM_001366230.1; = p.X160_splice on NM_001010000.3) | Splice Site (SNP) | VAF 56/239 reads (23%) | catalogued as COSV51634121; called by muse, mutect2, varscan2
- ARHGAP28 | c.1981A>G p.N661D (on ENST00000383472 / NM_001366230.1; = p.N502D on NM_001010000.3) | Missense Mutation (SNP) | VAF 97/254 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV51634147; called by muse, mutect2, varscan2
- ARHGAP30 | c.2929G>T p.E977* (on ENST00000368013 / NM_001025598.2; = p.E766* on NM_181720.3) | Nonsense Mutation (SNP) | VAF 30/99 reads (30%) | catalogued as COSV63515376; called by muse, mutect2, varscan2
- ARHGAP30 | c.2462G>T p.R821I | Missense Mutation (SNP) | VAF 215/550 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.157); catalogued as COSV63515383; called by muse, mutect2, varscan2
- ARHGAP32 | c.1867G>A p.E623K (on ENST00000310343 / NM_001378025.1; = p.E274K on NM_014715.4) | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs370678108; called by muse, mutect2, varscan2
- ARHGAP36 | c.1058A>C p.K353T | Missense Mutation (SNP) | VAF 101/310 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV52265134; called by muse, mutect2, varscan2
- ARHGAP6 | c.1629G>A p.E543= | Splice Region (SNP) | VAF 64/213 reads (30%) | catalogued as COSV100272070, COSV57293376; called by muse, mutect2, varscan2
- ARHGAP6 | c.998C>A p.S333Y | Missense Mutation (SNP) | VAF 105/375 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV100273319, COSV57293443; called by muse, varscan2
- ARHGAP6 | c.759G>T p.K253N | Missense Mutation (SNP) | VAF 131/414 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57293468; called by muse, mutect2, varscan2
- ARHGAP9 | c.1694C>A p.A565D (on ENST00000393797 / NM_001319850.2; = p.A546D on NM_032496.4) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV57359583; called by muse, mutect2, varscan2
- ARHGEF10 | c.910A>G p.K304E (on ENST00000398564; = p.K279E on NM_014629.4) | Missense Mutation (SNP) | VAF 95/305 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV50644261; called by muse, varscan2
- ARHGEF11 | c.3191C>A p.S1064* | Nonsense Mutation (SNP) | VAF 128/409 reads (31%) | catalogued as COSV59352900; called by muse, mutect2, varscan2
- ARHGEF12 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV63103349; called by muse, mutect2, varscan2
- ARHGEF15 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 63/160 reads (39%) | catalogued as COSV62724676; called by muse, mutect2, varscan2
- ARHGEF19 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV54615637; called by muse, mutect2, varscan2
- ARHGEF2 | c.836T>C p.L279P (on ENST00000361247 / NM_001162383.2; = p.L251P on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV58108040; called by muse, varscan2
- ARHGEF28 | c.4282C>T p.R1428C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55250915; called by muse, mutect2, varscan2
- ARHGEF35 | c.1454G>T p.*485Lext*14 | Nonstop Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV65312562; called by muse, mutect2, varscan2
- ARHGEF37 | c.607C>T p.L203F | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV61368291; called by muse, mutect2, varscan2
- ARHGEF39 | c.368A>C p.K123T | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs367995491; called by muse, mutect2, varscan2
- ARHGEF6 | c.1611G>T p.Q537H | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV51688738; called by muse, mutect2, varscan2
- ARHGEF6 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 97/333 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); catalogued as COSV51688761; called by muse, mutect2, varscan2
- ARID1A | c.2773G>T p.G925* | Nonsense Mutation (SNP) | VAF 88/259 reads (34%) | catalogued as COSV61374073; called by muse, mutect2, varscan2
- ARID1A | c.5290G>T p.E1764* | Nonsense Mutation (SNP) | VAF 46/126 reads (37%) | catalogued as COSV61374083; called by muse, mutect2, varscan2
- ARID2 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 102/354 reads (29%) | catalogued as COSV57599503; called by muse, mutect2, varscan2
- ARID2 | c.739C>A p.R247S | Missense Mutation (SNP) | VAF 85/234 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as COSV57599514, COSV57605252; called by muse, mutect2, varscan2
- ARID2 | c.4052G>T p.S1351I | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV57599525; called by muse, mutect2, varscan2
- ARID3C | c.933G>T p.E311D | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as COSV52406811; called by muse, mutect2, varscan2
- ARL13A | c.515A>G p.E172G | Missense Mutation (SNP) | VAF 86/276 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV65880045; called by muse, mutect2, varscan2
- ARL6 | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.864); catalogued as COSV60117229; called by muse, mutect2, varscan2
- ARL6 | c.179C>A p.S60* | Nonsense Mutation (SNP) | VAF 52/182 reads (29%) | catalogued as COSV60117242; called by muse, mutect2, varscan2
- ARL6 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 132/386 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.329); catalogued as rs200100002, COSV60117254; called by muse, mutect2, varscan2
- ARL6IP1 | c.269G>T p.R90I | Missense Mutation (SNP) | VAF 86/215 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV58614199, COSV58614483; called by muse, mutect2, varscan2
- ARMC2 | c.1092G>T p.K364N | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.081); catalogued as COSV64550448; called by muse, mutect2, varscan2
- ARMC3 | c.1923G>T p.K641N | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV53058753; called by muse, mutect2, varscan2
- ARMC3 | c.2140G>T p.E714* | Nonsense Mutation (SNP) | VAF 103/331 reads (31%) | catalogued as rs1183815996, COSV53058777; called by muse, mutect2, varscan2
- ARMC4 | c.2440C>A p.L814I | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100537275, COSV59459546; called by muse, mutect2, varscan2
- ARMC4 | c.1931C>A p.S644Y | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV59459566, COSV59463674; called by muse, varscan2
- ARMC5 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM149023, COSV51655516, COSV51660203; called by muse, mutect2, varscan2
- ARMC8 | c.857G>A p.R286Q (on ENST00000469044 / NM_001363941.2; = p.R272Q on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/346 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs924676663, COSV61767978; called by muse, mutect2, varscan2
- ARMC9 | c.1716C>T p.S572= | Splice Region (SNP) | VAF 41/110 reads (37%) | catalogued as rs758177199, COSV63020011; called by muse, mutect2, varscan2
- ARMCX3 | c.916C>A p.L306M | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57869981; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 69/201 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV63437335; called by muse, mutect2, varscan2
- ARMH4 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as COSV50762712; called by muse, mutect2, varscan2
- ARNT2 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 97/251 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs768601519, COSV57582940; called by muse, mutect2, varscan2
- ARNTL | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62985786; called by muse, mutect2, varscan2
- ARPC1A | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 181/488 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.964); catalogued as rs1336685684, COSV53556006; called by muse, mutect2, varscan2
- ARPC5 | c.443G>T p.R148I | Missense Mutation (SNP) | VAF 87/249 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54171169; called by muse, mutect2, varscan2
- ARPIN | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 189/566 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1339904406, COSV62589922; called by muse, mutect2, varscan2
- ARPP19 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 120/356 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as rs777862029, COSV51119163; called by muse, mutect2, varscan2
- ARPP21 | c.461T>C p.I154T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV51794305, COSV99491478; called by muse, mutect2, varscan2
- ARSF | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 17/535 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100839604; called by muse, mutect2
- ARSH | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated (0.97); PolyPhen benign (0.014); catalogued as COSV66962696; called by muse, mutect2, varscan2
- ARSJ | c.396A>G p.G132= | Splice Region (SNP) | VAF 36/96 reads (38%) | catalogued as rs757700061, COSV59537189; called by muse, mutect2, varscan2
- ARSK | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs780890433, COSV66169346; called by muse, mutect2, varscan2
- ART3 | c.662G>T p.R221I | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs550091630, COSV61913555; called by muse, mutect2, varscan2
- ART5 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 34/91 reads (37%) | catalogued as rs762141846, COSV63364256; called by muse, mutect2, varscan2
- ARV1 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as rs765301350, COSV59617312; called by muse, mutect2, varscan2
- AS3MT | c.933G>T p.K311N | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs757895180, COSV54916159; called by muse, mutect2, varscan2
- ASAP1 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.885); catalogued as rs759521913, COSV63046024; called by muse, mutect2, varscan2
- ASAP3 | c.2519C>T p.S840L | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1260013457, COSV60873426; called by muse, mutect2, varscan2
- ASB11 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV60354656; called by muse, mutect2, varscan2
- ASB11 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 50/128 reads (39%) | catalogued as COSV60354669; called by muse, mutect2, varscan2
- ASB12 | c.536C>A p.A179D | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as COSV62856396; called by muse, mutect2, varscan2
- ASB15 | c.1295T>G p.L432R | Missense Mutation (SNP) | VAF 89/312 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51924700; called by muse, mutect2, varscan2
- ASB3 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs780629471, COSV55074604; called by muse, mutect2, varscan2
- ASB4 | c.56G>T p.R19I | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV57507596, COSV99987137; called by muse, mutect2, varscan2
- ASCC2 | c.1570G>T p.E524* | Nonsense Mutation (SNP) | VAF 95/324 reads (29%) | catalogued as COSV57072679; called by muse, mutect2, varscan2
- ASCC3 | c.6088T>G p.L2030V | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.192); catalogued as COSV64973273; called by muse, mutect2, varscan2
- ASCC3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.357); catalogued as rs919581054, COSV100226137, COSV61225723; called by muse, mutect2, varscan2
- ASGR2 | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV54689678; called by muse, mutect2, varscan2
- ASH1L | c.8902C>T p.R2968* (on ENST00000368346 / NM_001366177.2; = p.R2963* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 38/153 reads (25%) | catalogued as rs143633976, COSV64206483; called by muse, mutect2, varscan2
- ASH1L | c.1401G>T p.K467N | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100853582; called by muse, varscan2
- ASH1L | c.523T>C p.S175P | Missense Mutation (SNP) | VAF 83/252 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV64206488; called by muse, mutect2, varscan2
- ASH2L | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 98/273 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1342895894, COSV51698982; called by muse, mutect2, varscan2
- ASIC1 | c.315G>T p.K105N | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.462); catalogued as COSV57316766; called by muse, mutect2, varscan2
- ASIC4 | c.1549G>T p.D517Y (on ENST00000347842 / NM_182847.3; = p.D536Y on NM_018674.6) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61731356, COSV61732023; called by muse, mutect2, varscan2
- ASIC5 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 25/88 reads (28%) | catalogued as COSV72232517, COSV72232612; called by muse, mutect2, varscan2
- ASMT | c.383G>T p.R128M | Missense Mutation (SNP) | VAF 150/414 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV67109700; called by muse, mutect2, varscan2
- ASPG | c.1166G>T p.G389V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV71933665; called by muse, mutect2, varscan2
- ASPM | c.9645G>A p.W3215* | Nonsense Mutation (SNP) | VAF 31/77 reads (40%) | catalogued as rs1394353328, COSV54126877; called by muse, mutect2, varscan2
- ASPM | c.8953C>A p.Q2985K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.213); catalogued as COSV54126885; called by muse, mutect2, varscan2
- ASPM | c.1845G>T p.K615N | Missense Mutation (SNP) | VAF 131/438 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as rs1557964854, COSV54126894; called by muse, mutect2, varscan2
- ASTN1 | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV99922888; called by muse, mutect2, varscan2
- ASTN2 | c.3891C>A p.F1297L (on ENST00000313400 / NM_001365069.1; = p.F1246L on NM_014010.5) | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs761740109, COSV56001231; called by muse, mutect2, varscan2
- ASXL1 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.065); catalogued as rs1190521844, COSV60105264; called by muse, mutect2, varscan2
- ASXL1 | c.3626G>A p.S1209N | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.018); catalogued as COSV60105274; called by muse, mutect2, varscan2
- ASXL2 | c.3428C>A p.S1143Y | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55455636, COSV55468622; called by muse, mutect2, varscan2
- ASXL3 | c.1154C>A p.S385Y | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV52461178; called by muse, mutect2, varscan2
- ASXL3 | c.2406G>T p.K802N | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.299); catalogued as COSV52461194; called by muse, mutect2, varscan2
- ATAD2 | c.2793A>T p.K931N | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99785207; called by muse, mutect2, varscan2
- ATAD2B | c.4338G>T p.E1446D | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV53196369; called by muse, mutect2, varscan2
- ATAD2B | c.4252G>T p.D1418Y | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.985); catalogued as COSV53195845, COSV53196378; called by muse, mutect2, varscan2
- ATAD2B | c.3962C>T p.S1321L | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.062); catalogued as rs765383233, COSV53196387; called by muse, mutect2, varscan2
- ATAD2B | c.3065A>C p.D1022A | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as COSV53196393; called by muse, mutect2, varscan2
- ATAD2B | c.2741A>G p.Q914R | Missense Mutation (SNP) | VAF 94/373 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as rs1272805719, COSV53196405; called by muse, mutect2, varscan2
- ATAD2B | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53196411; called by muse, mutect2, varscan2
- ATAD2B | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 155/531 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV53196418; called by muse, mutect2, varscan2
- ATAD3B | c.300G>T p.E100D (on ENST00000308647; = p.E154D on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/380 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV58019839; called by muse, mutect2, varscan2
- ATAD5 | c.510A>C p.E170D | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.351); catalogued as COSV58972981; called by muse, mutect2, varscan2
- ATAD5 | c.3085G>T p.E1029* | Nonsense Mutation (SNP) | VAF 43/127 reads (34%) | catalogued as COSV58972990; called by muse, mutect2, varscan2
- ATF1 | c.126G>T p.Q42H | Missense Mutation (SNP) | VAF 78/236 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV50394231; called by muse, varscan2
- ATF2 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 62/203 reads (31%) | catalogued as COSV51368306; called by muse, mutect2, varscan2
- ATF7 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 124/353 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1463954473, COSV60642683; called by muse, mutect2, varscan2
- ATF7IP | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 35/112 reads (31%) | catalogued as COSV53768016; called by muse, mutect2, varscan2
- ATF7IP | c.1049A>G p.E350G | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.011); catalogued as COSV99662073; called by muse, mutect2
- ATF7IP | c.1468G>T p.E490* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV53768038; called by muse, mutect2, varscan2
- ATF7IP | c.1673A>C p.K558T | Missense Mutation (SNP) | VAF 83/293 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV53768047; called by muse, mutect2, varscan2
- ATF7IP2 | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV61092605; called by muse, mutect2, varscan2
- ATG16L1 | c.954C>T p.F318= (on ENST00000392017 / NM_030803.7; = p.F299= on NM_017974.4) | Splice Region (SNP) | VAF 117/304 reads (38%) | catalogued as rs776787304, COSV61464859; called by muse, varscan2
- ATG16L1 | c.1195C>T p.R399* (on ENST00000392017 / NM_030803.7; = p.R380* on NM_017974.4) | Nonsense Mutation (SNP) | VAF 108/373 reads (29%) | catalogued as COSV61464865; called by muse, mutect2, varscan2
- ATG2B | c.3281T>G p.F1094C | Missense Mutation (SNP) | VAF 97/232 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV63422346; called by muse, mutect2, varscan2
- ATG2B | c.2435T>C p.I812T | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV63422351; called by muse, mutect2, varscan2
- ATG4C | c.137A>C p.K46T | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV58604390; called by muse, mutect2, varscan2
- ATG4C | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | catalogued as COSV58604062; called by muse, mutect2, varscan2
- ATG4C | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 31/123 reads (25%) | catalogued as COSV58604414; called by muse, mutect2, varscan2
- ATG7 | c.2012C>A p.S671Y | Missense Mutation (SNP) | VAF 75/245 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs756579901, COSV61611640; called by muse, mutect2, varscan2
- ATG9B | c.2233A>G p.T745A | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV99872098; called by muse, mutect2
- ATIC | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs199518893, COSV52692257; called by muse, mutect2, varscan2
- ATL1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs976793999, COSV63296138; called by muse, mutect2, varscan2
- ATM | c.8435C>A p.S2812Y | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.735); catalogued as CD162053, COSV53734098; called by muse, mutect2, varscan2
- ATOH1 | c.579G>T p.K193N | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV60037366; called by muse, mutect2, varscan2
- ATP10A | c.4388C>T p.A1463V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.058); catalogued as COSV63515127; called by muse, mutect2, varscan2
- ATP10A | c.628C>A p.Q210K | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV63515139; called by muse, mutect2, varscan2
- ATP10D | c.4015A>G p.T1339A | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV56688541; called by muse, mutect2, varscan2
- ATP11A | c.2658C>A p.F886L | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV52108296, COSV52111338; called by muse, mutect2, varscan2
- ATP11C | c.3188T>C p.M1063T | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.597); catalogued as COSV59560845; called by muse, mutect2, varscan2
- ATP12A | c.84G>T p.K28N | Missense Mutation (SNP) | VAF 73/233 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.244); catalogued as rs1380799958, COSV54513912; called by muse, mutect2, varscan2
- ATP12A | c.1678C>A p.L560M | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV54513922; called by muse, mutect2, varscan2
- ATP12A | c.2045G>A p.G682D | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54513931; called by muse, mutect2, varscan2
- ATP12A | c.2396T>G p.I799S | Missense Mutation (SNP) | VAF 131/377 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV54513941; called by muse, mutect2, varscan2
- ATP13A3 | c.3184G>A p.E1062K | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs531855588, COSV55462596; called by muse, mutect2, varscan2
- ATP13A4 | c.1145G>T p.R382I | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55067462; called by muse, mutect2, varscan2
- ATP13A5 | c.2014G>T p.E672* | Nonsense Mutation (SNP) | VAF 26/118 reads (22%) | catalogued as COSV60867353; called by muse, mutect2, varscan2
- ATP1A1 | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV55190315; called by muse, mutect2, varscan2
- ATP1A2 | c.958A>C p.I320L | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV63402931; called by muse, mutect2, varscan2
- ATP1A2 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.113); catalogued as rs139499540; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP1A3 | c.752A>G p.N251S (on ENST00000545399 / NM_001256214.2; = p.N238S on NM_152296.5) | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.281); catalogued as rs782467046, COSV57486217; called by muse, varscan2
- ATP1B1 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 58/204 reads (28%) | catalogued as COSV63179036; called by muse, mutect2, varscan2
- ATP1B4 | c.665T>G p.F222C (on ENST00000218008 / NM_001142447.3; = p.F218C on NM_012069.5) | Missense Mutation (SNP) | VAF 77/252 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54311770; called by muse, mutect2, varscan2
- ATP23 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 145/508 reads (29%) | catalogued as COSV55685646; called by muse, mutect2, varscan2
- ATP2A1 | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs200278446, COSV62868845, COSV62869777; called by muse, mutect2, varscan2
- ATP2A3 | c.164A>G p.E55G | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV59227398; called by muse, mutect2, varscan2
- ATP2B1 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV53805635; called by muse, mutect2, varscan2
- ATP2B2 | c.947C>T p.A316V (on ENST00000352432; = p.A327V on NM_001001331.4) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.312); catalogued as rs149708084, COSV59508064; called by muse, mutect2, varscan2
- ATP2B3 | c.1564T>C p.Y522H | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV99685650; called by muse, mutect2, varscan2
- ATP2B4 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58173908, COSV58175522; called by muse, mutect2, varscan2
- ATP2C2 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV52293996, COSV52302441; called by muse, mutect2, varscan2
- ATP2C2 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 117/371 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs372103955; called by muse, mutect2, varscan2
- ATP2C2 | c.1794G>T p.M598I | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV52294026, COSV52299192; called by muse, mutect2, varscan2
- ATP4A | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 127/389 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV52866740; called by muse, mutect2, varscan2
- ATP5F1D | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753537314, COSV53066557; called by muse, mutect2, varscan2
- ATP5IF1 | c.319T>G p.*107Eext*23 | Nonstop Mutation (SNP) | VAF 60/164 reads (37%) | catalogued as COSV55281072; called by muse, mutect2, varscan2
- ATP5PD | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.073); catalogued as rs377594522, COSV56902613; called by muse, mutect2, varscan2
- ATP6V0A4 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 162/522 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as CM065976, COSV59473810; called by muse, mutect2, varscan2
- ATP6V0D2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs201622171; called by muse, mutect2, varscan2
- ATP6V0D2 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 88/302 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as rs781030035, COSV53413746; called by muse, mutect2, varscan2
- ATP6V1B1 | c.509C>A p.P170H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV52268630; called by muse, mutect2, varscan2
- ATP6V1C2 | c.591A>C p.Q197H | Missense Mutation (SNP) | VAF 131/388 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.91); catalogued as COSV55358768; called by muse, varscan2
- ATP6V1E1 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs775186565, COSV53657433; called by muse, mutect2, varscan2
- ATP6V1H | c.1389C>T p.N463= | Splice Region (SNP) | VAF 24/54 reads (44%) | catalogued as COSV62217506; called by muse, mutect2, varscan2
- ATP8A1 | c.1664G>T p.R555I | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52531131; called by muse, mutect2, varscan2
- ATP8A2 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54943466, COSV99683072; called by muse, mutect2, varscan2
- ATP8A2 | c.892-1G>T p.X298_splice | Splice Site (SNP) | VAF 117/346 reads (34%) | catalogued as COSV54943474; called by muse, mutect2, varscan2
- ATP8B1 | c.3073G>T p.D1025Y | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV52173812; called by muse, mutect2, varscan2
- ATP8B2 | c.2545G>A p.A849T (on ENST00000672630; = p.A816T on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/285 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59245348; called by muse, mutect2, varscan2
- ATP8B2 | c.2814C>A p.F938L (on ENST00000672630; = p.F905L on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV59245353; called by muse, mutect2, varscan2
- ATP8B4 | c.2613A>T p.K871N | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV52711666; called by muse, mutect2, varscan2
- ATP8B4 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs374330624; called by muse, mutect2, varscan2
- ATPAF1 | c.856G>T p.E286* (on ENST00000574428; = p.E309* on NM_022745.4) | Nonsense Mutation (SNP) | VAF 78/204 reads (38%) | catalogued as COSV61304582; called by muse, mutect2, varscan2
- ATR | c.4235G>A p.R1412Q | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.63); catalogued as rs371292374, COSV63384323; called by muse, mutect2, varscan2
- ATR | c.2051C>A p.S684Y | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV63385127; called by muse, mutect2, varscan2
- ATRNL1 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV61800070; called by muse, mutect2, varscan2
- ATRNL1 | c.4103G>A p.R1368Q | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as rs782128195, COSV100370029, COSV58079079; called by muse, mutect2, varscan2
- ATRX | c.6815A>G p.K2272R | Missense Mutation (SNP) | VAF 112/335 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV64873544; called by muse, varscan2
- ATRX | c.4639G>T p.E1547* | Nonsense Mutation (SNP) | VAF 107/299 reads (36%) | catalogued as COSV64873561; called by muse, mutect2, varscan2
- ATRX | c.3557G>T p.R1186I | Missense Mutation (SNP) | VAF 88/371 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as COSV100971344; called by muse, mutect2
10,339 further variants in this file (8,065 protein-altering or splice-affecting, 2,047 silent, 227 other) are not listed here.
